Somatic mutation profile of tumor specimen TCGA-LP-A5U3-01A (aliquot TCGA-LP-A5U3-01A-11D-A28B-09) from TCGA case TCGA-LP-A5U3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 40.2 years (14,698 days).
Specimen TCGA-LP-A5U3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54338951-9ba5-4e67-8807-edd42d3394c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LP-A5U3-10A (Blood Derived Normal), aliquot TCGA-LP-A5U3-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70ea6f8e-eb9d-4478-88cf-43f1ff6ffa9b

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 3, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10L | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV63416416; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.99); catalogued as COSV59473476; called by muse, mutect2, varscan2
- CCDC28B | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52207917; called by muse, mutect2, varscan2
- CDH19 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50955359; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as COSV62572767; called by muse, mutect2, varscan2
- CPZ | c.998A>G p.Y333C (on ENST00000360986 / NM_001014447.3; = p.Y322C on NM_003652.3) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989941657, COSV59921962; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- F9 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as CM940526, COSV54379223; called by muse, mutect2, varscan2
- FOSB | c.498A>C p.K166N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62278448; called by muse, mutect2, varscan2
- FTHL17 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV63266556; called by muse, mutect2
- GNAI3 | c.611A>G p.Q204R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs935291032, COSV63983378; called by muse, mutect2, varscan2
- GPATCH2L | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV55047254; called by muse, mutect2, varscan2
- GPR173 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs781986623, COSV60233793; called by muse, mutect2, varscan2
- GPRASP1 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV64355020; called by muse, mutect2, varscan2
- GUCY1A1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs139274399; called by muse, mutect2, varscan2
- HTR5A | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs763809843, COSV55281303; called by muse, mutect2, varscan2
- ITGB4 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs778595251, COSV52322775; called by muse, mutect2, varscan2
- KIAA1217 | c.5626C>T p.L1876F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs375951552; called by muse, mutect2, varscan2
- MAGI1 | c.2847C>G p.S949R (on ENST00000402939 / NM_001033057.2; = p.S977R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.357); catalogued as COSV58317993; called by muse, mutect2, varscan2
- MGA | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 27/45 reads (60%) | catalogued as COSV54950530; called by muse, mutect2, varscan2
- NHS | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs767956070, COSV66272541, COSV66282606; called by muse, mutect2, varscan2
- RNF139 | c.1374C>G p.D458E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52678241; called by muse, mutect2
- SAR1B | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV68391388; called by muse, mutect2, varscan2
- SIX6 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs78954112; called by muse, mutect2, varscan2
- SPRR1B | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 86/136 reads (63%) | catalogued as COSV61067488; called by muse, mutect2, varscan2
- SULT2B1 | c.883C>T p.R295C (on ENST00000201586 / NM_177973.2; = p.R280C on NM_004605.2) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs920026531, COSV52374955; called by muse, mutect2, varscan2
- SYNE1 | c.8011C>T p.L2671F (on ENST00000367255 / NM_182961.4; = p.L2678F on NM_033071.3) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54928614; called by muse, mutect2, varscan2
- TH | c.738C>T p.H246= (on ENST00000381178 / NM_199292.3; = p.H215= on NM_000360.4) | Splice Region (SNP) | VAF 19/25 reads (76%) | catalogued as rs768037080, COSV60767693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIP11 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV50914614, COSV50918899; called by muse, mutect2, varscan2
- VPS13C | c.3298G>A p.E1100K (on ENST00000644861 / NM_020821.3; = p.E1057K on NM_017684.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.427); catalogued as COSV51125616; called by muse, mutect2, varscan2
- WDTC1 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV60087478; called by muse, mutect2, varscan2
- ZGRF1 | c.165G>A p.V55= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as rs754231318, COSV52198824; called by muse, mutect2, varscan2
- SLC22A13 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CCDC77 | c.201T>G p.A67= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV53472214; called by muse, mutect2, varscan2
- ELK1 | c.156G>A p.K52= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV55952254; called by muse, mutect2, varscan2
- FOXL1 | c.72G>A p.E24= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV57213866; called by muse, mutect2, varscan2
- ITGAD | c.2901C>T p.N967= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV54931636; called by muse, mutect2, varscan2
- PAK1 | c.261C>T p.V87= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs141395962; called by muse, mutect2, varscan2
- PEG3 | c.984G>A p.S328= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs766518038, COSV55628121; called by muse, mutect2, varscan2
- PIP4K2C | c.738C>T p.L246= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100533388; called by muse, mutect2, varscan2
- SLC29A1 | c.318C>T p.I106= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV57577492; called by mutect2, varscan2
- SNX29 | c.37C>T p.L13= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV73829686, COSV73829856; called by muse, mutect2, varscan2
- VSIG10 | c.462C>T p.N154= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1380249209, COSV63652398; called by muse, mutect2, varscan2
- ZFHX3 | c.-810G>A | 5'UTR (SNP) | VAF 13/63 reads (21%) | catalogued as rs373706877; called by muse, mutect2, varscan2
